Surgical pathology report (de-identified scan), TCGA case TCGA-24-2298, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2298-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL WITH ADDENDUM

*** Converted Case * This report may not match the original report format**

Physician(s):

TCGA-24-2298

DIAGNOSIS:

OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA

FALLOPIAN TUBES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA,
METASTATIC

SOFT TISSUE, SIGMOID EPIPLOICA, BIOPSY
- PAPILLARY SEROUS ADENOCARCINOMA,
METASTATIC

SOFT TISSUE, "PELVIC TUMOR," BIOPSY
- PAPILLARY SEROUS ADENOCARCINOMA,
METASTATIC

SOFT TISSUE, "SIGMOID MESENTERY," BIOPSY
- PAPILLARY SEROUS ADENOCARCINOMA,
METASTATIC

SOFT TISSUE, RIGHT UPPER QUADRANT MASS, BIOPSY
- PAPILLARY SEROUS ADENOCARCINOMA,
METASTATIC

SOFT TISSUE, DESCENDING COLON, BIOPSY
- PAPILLARY SEROUS ADENOCARCINOMA,
METASTATIC

SOFT TISSUE, UMBILICUS, HERNIORRHAPHY
- PAPILLARY SEROUS ADENOCARCINOMA,
METASTATIC

OMENTUM, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

UTERUS, SEROSA, ABDOMINAL HYSTERECTOMY - PAPILLARY SEROUS
ADENOCARCINOMA,
METASTATIC

UTERUS, CERVIX, ABDOMINAL HYSTERECTOMY - NO HISTOPATHOLOGIC
ABNORMALITIES

UTERUS, ENDOMETRIUM, ABDOMINAL HYSTERECTOMY - ATROPHIC

UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY - NO HISTOPATHOLOGIC
ABNORMALITIES

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion

Intraoperative Consultation:

FS1: Ovary, TAH-BSO

- "Poorly differentiated carcinoma with suggestions of papillary formation and psammoma bodies"
- "Consistent with ovarian primary"
- "Not consistent with breast primary"

Microscopic Description and Comment:

There is widely disseminated, poorly differentiated papillary serous carcinoma involving both right and left ovaries, right and left paratubal soft tissue, serosal surface of the uterus, and biopsies submitted as sigmoid epiploica, pelvic tumor, right upper quadrant mass, sigmoid mesentery, descending colon, and umbilicus. The omentum is also extensively replaced by metastatic serous carcinoma. A few small nests of tumor are floating in the lumen of the left fallopian tube. The tumor cells are pleomorphic with large hyperchromatic nuclei and a high mitotic rate. Psammoma bodies are numerous. There is considerable lymphatic involvement especially in sections of the right ovary.

The endometrium is inactive. There are no significant histopathologic changes in the myometrium or the cervix.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
2. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor DOES invade the mesovarium.
7. Tumor involves the adjacent fallopian tube.
8. Tumor DOES invade the pelvic soft tissue.
9. Tumor involvement of the pelvic peritoneum is PRESENT.
10. Metastatic involvement of the EXTRAPELVIC peritoneum is PRESENT.
11. Metastatic involvement of the omentum is PRESENT.
13. Metastatic involvement of the uterine serosa is PRESENT.
14. Metastatic involvement of the endometrium is ABSENT.
15. Regional lymph node metastases CANNOT BE EVALUATED.
16. The total number of regional lymph nodes examined is 0.
18. DETAILED STAGING INFORMATION: Requires clinical input.
19. The FINAL AJCC/FIGO STAGE IS: Not evaluable

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

History:

The patient is a [REDACTED] with a history of breast cancer [REDACTED] presents with bilateral ovarian masses and omental caking. Operative procedure: Total abdominal hysterectomy and bilateral salpingo-oophorectomy. An intraoperative non-microscopic consultation was obtained and interpreted as: "TAH, BSO - 190 gram specimen with both ovaries containing tumor, questionable fallopian tube vs. ligament with tumor. Tumor fragments given to surgeon. Touch prep shows highly malignant cells" by [REDACTED]

Specimen(s) Received:

A: FS OVARY, TAH-BSO
B: X OVARY, TAH-BSO
C: OMENTUM
D: SIGMOID EPIPLOAICA
E: PELVIC TUMOR
F: SIGMOID MESSENTERY
G: RUQ MASS
H: DESCENDING COLON
I: UMBILICAL HERNIA SAC

Gross Description:

The specimens are received in nine containers of formalin each labelled with the patient's name. The first container is labelled "uterus, cervix and BSO." It contains a uterus and cervix with bilaterally attached adnexa. The uterus with cervix alone weighs 64 grams and measures 7.4 x 7.0 x 2.8 cm in greatest dimension. Both the anterior and posterior serosal surfaces are studded by tan tumor nodules. These are most prominent on the anterior surface. The serosa otherwise is tan smooth and shiny. The endometrial cavity measures 2.9 x 2.6 cm in greatest dimension. It is lined by glistening yellow-tan endometrium. The endometrium measures ~0.1 cm in greatest depth and is unremarkable. It overlies solid pink-tan myometrium which measures 1.5 cm in maximal depth. No leiomyomata are present. The endocervix measures 3 cm in length and is lined by unremarkable yellow, furrowed mucosa. Sectioning reveals occasional nabothian cysts. The cervical os measures ~1 cm; the ectocervix is lined by unremarkable smooth white epithelium.

The right ovary measures 5 x 2.5 x 1.9 cm in greatest dimension and is largely replaced by tan nodular friable tumor. The tumor studs the broad ligament and the surface of the fallopian tube. The fallopian tube measures 3.5 cm in length by 0.4 cm in average diameter. No intrinsic abnormalities of the fallopian tube are identified. The left ovary measures 2.6 x 2.4 x 1.4 cm in greatest dimension and is also replaced by tan nodular friable tumor. The tumor studs the broad ligament. A convoluted fimbriated fallopian tube measuring 2.5 cm in length by 0.7 cm in average diameter is also present. No intrinsic abnormalities of the tube are identified. Labelled EM1, anterior endomyometrium; EM2, posterior endomyometrium; C1, anterior cervix; C2, posterior cervix; RO1-RO3, right ovary; RT, right tube and broad ligament; LO1-LO3, left ovary; LT, left tube and broad ligament.

The second container is labelled "FS1" and contains an irregular tan glistening fragment of tissue measuring 1 x 0.7 x 0.1 cm. Labelled FS1. Jar 0.

The third container is labelled "sigmoid epiploica." It contains two irregular firm yellow and white nodular pieces of tissue measuring 1.8 x 1.5 x 0.5 cm and 2.0 x 1.5 x 0.9 cm. Labelled A. Jar 1.

The fourth container is labelled "pelvic tumor" and contains two irregular shaggy pieces of tan tissue measuring 2.0 x 1.5 x 0.5 cm and 1.8 x 1.6 x 0.3 cm. Labelled B. Jar 1.

The fifth container is labelled "sigmoid mesentery" and contains two irregular fragments of shaggy tan tissue consistent with tumor. The tissue measures 2.0 x 1.5 x 1.3 cm and 2.0 x 1.6 x 1.0 cm in greatest dimension. Labelled C. Jar 1.

The sixth container is labelled "right upper quadrant mass." It contains four irregular pieces of tan nodular tissue consistent with tumor tissue admixed with fibroadipose tissue. In aggregate

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

the specimen measures 3.5 x 2.5 x 1.5 cm in greatest dimension.
Labelled D. Jar 1.

The seventh container is labelled "descending colon." It contains two irregular nodular pieces of tan tissue consistent with tumor. These pieces measure 1.5 x 1.3 x 0.9 cm and 1.7 x 1.3 x 0.5 cm. Labelled E. Jar 1.

The eighth container is labelled "umbilical hernia." It consists of a irregular membranous sheet of tissue with attached fibroadipose tissue. The tissue measures 7.5 x 3.5 x 0.4 cm in greatest dimension. Also present is a smaller fragment of tissue of a similar nature measuring 2 x 1.5 x 0.3 cm. A tan tumor nodule measuring 0.5 cm in greatest dimension is identified in the larger piece of tissue. Labelled F. Jar 1.

The ninth container is labelled "omentum." It contains a 30 x 15 x 3 cm sheet of omental tissue massively studded by tumor nodules ranging in size from minute to 10 cm in greatest dimension. Also present are two irregular pieces of tumor measuring 3 and 7 cm in greatest dimension. Labelled G, section of omentum. Jar 2.

Addenda/Procedures

Addendum Ordered:

Status: Signed Out

Source: NCI Genomic Data Commons file 968a5f53-d797-4591-8086-aed7874dbff7 (TCGA-24-2298.FE9D7BF4-A278-4842-B911-018D0127EF20.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).